Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A69P, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A69P-06A (Metastatic).

ICD-O-3

Melanoma, malignant NOS
8720/3
Site Femoral lymph node
C77.4

QW 5/16/13

Diagnosis:

A: Left buttock, shave

-Biopsy site changes and residual melanocytic nevus with congenital features, excised in the planes of section examined

B: Lymph nodes, right femoral contents, removal

-Metastatic melanoma involving 3 out of 12 matted lymph nodes, with the largest diameter measuring 5 cm (3/12)

-Extracapsular extension is extensive

C: Lymph nodes, right femoral canal, removal

-No evidence of melanoma or lymph node tissue

-The entire specimen was submitted and examined microscopically

Clinical History:

-year-old female with melanoma

Gross Description:

A: The specimen was received labeled with the patient's name and measured 13 x 11 x 4 mm.

B: The specimen was received labeled with the patient's name and measured 10 x 7.5 x 4 cm. The fibrofatty specimen is serially sectioned and reveals a 5 x 3.5 x 2 cm aggregate of tan matted lymph nodes. Fresh tumor is given to tissue procurement. The specimen is then placed in . Lymph node candidates are identified and submitted as B1-B9. Tissue remains in formalin.

C: The specimen was received labeled with the patient's name and measured 3 x 2.8 x 1.4 cm. The tissue is entirely submitted as C1-4,

Local/Regional/Primary Notes		☒
Case is (re)stage		☒
Date/Time	5/3/13	
QUA-APPROVED	4/30/13	

Source: NCI Genomic Data Commons file 5de40856-f4c8-4f6a-8503-927310b58869 (TCGA-FR-A69P.E0EA0F08-1A13-4D3E-BA89-1192DE2FC8A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).